Gene-level copy-number profile of tumor specimen HTMCP-03-06-02042-01B from CGCI case HTMCP-03-06-02042, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 82.2 years (30,023 days).
Specimen HTMCP-03-06-02042-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6dc09bcc-767f-408c-8738-1ad70205a30c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02042-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/e7e900d5-0285-4f66-86b1-f52d17074a1a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 6,701; copy number 2: 44,923; copy number 3: 5,505; copy number 4: 1,024; copy number 5: 212; copy number 7: 7; copy number 14: 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,702,379–1,745,992, 4 genes (within-gene range 0–2): CDK11A, AL031282.2, AL031282.1, SLC35E2A.
- chr1:16,739,938–16,972,964, 14 genes: AL021920.3, CROCC, CROCCP4, RNU1-4, MST1L, BX284668.1, BX284668.3, MIR3675, BX284668.2, RNU1-5P, BX284668.5, BX284668.4, RNU1-2, BX284668.6.
- chr10:46,233,885–46,273,557, 1 gene: ANTXRLP1.
- chr15:34,415,450–34,521,791, 4 genes (within-gene range 0–1): AC025678.3, HNRNPLP2, FSCN1P1, DNM1P5.
- chr16:70,852,698–70,852,814, 1 gene (within-gene range 0–2): RNU6ATAC25P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 220 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,008,420–151,125,542, 7 genes, copy number 7 (within-gene range 4–7): PRUNE1, RNU6-884P, BNIPL, C1orf56, CDC42SE1, MLLT11, GABPB2.
- chr7:63,632,608–63,636,617, 1 gene, copy number 14: AC006015.1.
- chr9:212,824–17,503,923, 210 genes, copy number 5 (broad region; genes not listed).
- chr20:31,605,283–31,607,240, 2 genes, copy number 5: ID1, MIR3193.

Autosomal genes at a single copy (total copy number 1): 6,679. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
